Somatic mutation profile of tumor specimen TCGA-CJ-4916-01A (aliquot TCGA-CJ-4916-01A-01D-1429-08) from TCGA case TCGA-CJ-4916, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 69.7 years (25,470 days).
Specimen TCGA-CJ-4916-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8d69c97-83ee-4ce4-88cc-882dcdaf479b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CJ-4916-11A (Solid Tissue Normal), aliquot TCGA-CJ-4916-11A-01D-1429-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98b6da53-731a-4a7c-9638-21bf24128419

The open-access MAF lists 48 somatic variants for this specimen: 36 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 29, Silent 12, Frame Shift Del 2, Splice Site 2, In Frame Del 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACACB | c.6926A>G p.E2309G | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.947); catalogued as COSV58135728; called by muse, mutect2, varscan2
- ADGRG7 | c.597+2T>A p.X199_splice | Splice Site (SNP) | VAF 14/94 reads (15%) | catalogued as COSV56297140; called by muse, mutect2
- ANOS1 | c.1526G>T p.S509I | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.333); catalogued as COSV52920644; called by muse, mutect2, varscan2
- AXL | c.354G>C p.L118F | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.174); catalogued as COSV56568910, COSV99996009; called by muse, mutect2, varscan2
- BTAF1 | c.5008C>T p.P1670S | Missense Mutation (SNP) | VAF 68/312 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as COSV56434636; called by muse, mutect2, varscan2
- CRYBG3 | c.7649A>T p.N2550I | Missense Mutation (SNP) | VAF 59/279 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.116); catalogued as COSV51712308; called by muse, mutect2, varscan2
- DCHS1 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV55036234; called by muse, mutect2, varscan2
- DNAH10 | c.1306T>A p.W436R (on ENST00000409039; = p.W375R on NM_207437.3) | Missense Mutation (SNP) | VAF 43/193 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199697349, COSV68994625; called by muse, mutect2, varscan2
- DTNA | c.2036G>T p.G679V | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.196); catalogued as rs150410546, COSV52005396; called by muse, mutect2, varscan2
- FAM91A1 | c.1874T>A p.L625Q | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as COSV58237374; called by muse, mutect2, varscan2
- FBXL14 | c.1037A>G p.K346R | Missense Mutation (SNP) | VAF 41/201 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.339); catalogued as COSV59336505; called by muse, mutect2, varscan2
- FBXO11 | c.524A>G p.D175G (on ENST00000403359 / NM_001190274.2; = p.D91G on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as rs776562972, COSV57020136; called by muse, mutect2, varscan2
- GAPDHS | c.287A>G p.E96G | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.238); catalogued as rs756319536, COSV55882769; called by muse, mutect2, varscan2
- JADE1 | c.1558T>A p.C520S | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.968); catalogued as COSV56906277; called by muse, mutect2, varscan2
- MIA3 | c.164A>C p.D55A | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60513454; called by muse, mutect2, varscan2
- NTF4 | c.404A>G p.Y135C | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56824856; called by muse, mutect2, varscan2
- OR2L8 | c.812A>T p.K271M | Missense Mutation (SNP) | VAF 30/240 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.782); catalogued as COSV61726977, COSV61727225; called by muse, mutect2, varscan2
- PELI2 | c.574G>T p.V192L | Missense Mutation (SNP) | VAF 43/224 reads (19%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.989); catalogued as COSV50711543; called by muse, mutect2, varscan2
- PPP1R13L | c.43A>G p.M15V | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs752804434, COSV62908618; called by muse, mutect2, varscan2
- SEPTIN4 | c.730C>A p.P244T | Missense Mutation (SNP) | VAF 62/320 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.031); catalogued as COSV58727023, COSV58728057; called by muse, mutect2, varscan2
- SMC5 | c.1969G>A p.E657K | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0.062); catalogued as COSV63193166; called by muse, mutect2, varscan2
- STAG2 | c.603T>G p.I201M | Missense Mutation (SNP) | VAF 138/634 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV54359865; called by muse, mutect2, varscan2
- STK36 | c.2611G>T p.D871Y | Missense Mutation (SNP) | VAF 102/574 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.417); catalogued as COSV55327063; called by muse, mutect2, varscan2
- TAF1C | c.319A>G p.I107V | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as rs1320030262, COSV58986809; called by muse, mutect2, varscan2
- TCEAL2 | c.429C>A p.N143K | Missense Mutation (SNP) | VAF 52/229 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.807); catalogued as COSV61197424; called by muse, mutect2, varscan2
- TOGARAM1 | c.1555C>G p.L519V | Missense Mutation (SNP) | VAF 72/274 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753984118, COSV61888259; called by muse, mutect2, varscan2
- XRCC5 | c.1345G>A p.A449T | Missense Mutation (SNP) | VAF 53/260 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.024); catalogued as rs772908780, COSV67536389; called by muse, mutect2, varscan2
- ZNF117 | c.586G>T p.E196* | Nonsense Mutation (SNP) | VAF 7/201 reads (3%) | catalogued as COSV51427986; called by muse, mutect2
- ZNF423 | c.2243C>T p.A748V (on ENST00000563137 / NM_001379286.1; = p.A740V on NM_015069.4) | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs923711687, COSV52176934; called by muse, mutect2, varscan2
- ZWINT | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV59185512; called by muse, mutect2, varscan2
- ABCC5 | c.825+1del p.X275_splice | Splice Site (DEL) | VAF 16/91 reads (18%) | called by mutect2, pindel, varscan2
- CCL3 | c.28G>T p.V10F | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.646); called by muse, mutect2
- KLF15 | c.949_951del p.L317del | In Frame Del (DEL) | VAF 6/26 reads (23%) | called by mutect2, pindel, varscan2
- LGSN | c.200del p.P67Lfs*7 | Frame Shift Del (DEL) | VAF 14/133 reads (11%) | called by mutect2, pindel, varscan2
- PBRM1 | c.3376_3380del p.N1126Gfs*15 (on ENST00000296302 / NM_001366071.2; = p.N1101Gfs*15 on NM_018313.5) | Frame Shift Del (DEL) | VAF 68/306 reads (22%) | called by mutect2, pindel, varscan2
- POMT2 | c.804dup p.S269Qfs*39 | Frame Shift Ins (INS) | VAF 52/254 reads (20%) | called by mutect2, pindel, varscan2
- ACTBL2 | c.825C>T p.I275= | Silent (SNP) | VAF 25/125 reads (20%) | catalogued as COSV70661324; called by muse, mutect2, varscan2
- AHSG | c.504G>T p.L168= | Silent (SNP) | VAF 29/189 reads (15%) | catalogued as COSV56607953; called by muse, mutect2, varscan2
- CCDC93 | c.139T>C p.L47= | Silent (SNP) | VAF 45/292 reads (15%) | catalogued as COSV60121575; called by muse, mutect2, varscan2
- CCND3 | c.705T>C p.T235= | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as COSV57828613; called by muse, mutect2, varscan2
- CENPI | c.774G>A p.K258= | Silent (SNP) | VAF 112/558 reads (20%) | catalogued as COSV54503084; called by muse, mutect2, varscan2
- ITGAV | c.723G>A p.R241= | Silent (SNP) | VAF 37/288 reads (13%) | catalogued as rs201616731, COSV53713268; called by muse, mutect2, varscan2
- MET | c.789G>T p.T263= | Silent (SNP) | VAF 75/451 reads (17%) | catalogued as COSV59261968; called by muse, mutect2, varscan2
- PELI2 | c.573G>T p.L191= | Silent (SNP) | VAF 45/224 reads (20%) | catalogued as COSV50711522; called by muse, mutect2, varscan2
- SCN10A | c.822T>C p.N274= | Silent (SNP) | VAF 33/159 reads (21%) | catalogued as COSV71861677; called by muse, mutect2, varscan2
- SERPINB10 | c.771C>T p.D257= | Silent (SNP) | VAF 51/256 reads (20%) | catalogued as rs1426950334, COSV53073406; called by muse, mutect2, varscan2
- TNKS1BP1 | c.570C>T p.N190= | Silent (SNP) | VAF 32/170 reads (19%) | catalogued as COSV64101203; called by muse, mutect2, varscan2
- TTYH2 | c.468G>T p.R156= | Silent (SNP) | VAF 41/265 reads (15%) | catalogued as COSV53910847; called by muse, mutect2, varscan2
